Surgical pathology report (de-identified scan), TCGA case TCGA-66-2789, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2789-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lower lobe

Clinical diagnosis and question

Unclear space-occupying lesion S9 left, S10 left. Questionable asbestos.

REPORT ON FINDINGS**Macroscopy**

- 1.) Wedge left lower lobe: after removal of the angled, 13 cm long staple suture line, inflated, fixed lung resection tissue measuring 10 x 2 cm at the base, up to 4.5 cm thick, with pleural margin. Visceral pleura shows slightly reticulate blackish pigmentation with an eccentric 2 cm area of star-shape retraction. Under this is a whitish tumor, 1.9 cm in size, with unclear demarcation, at a distance of 0.1 cm from the staple suture line. Rest of parenchyma shows partial rarefaction with the formation of lacunae max. 0.2 cm in size.
- 2.) Left lower lobe: inflated, fixed left lower lobe measuring 17 x 7 cm at the base, up to 20.5 cm high. Central bronchus resection plane located at the level of bifurcation B6. At the hilus two partly lesioned nodes, 0.7 cm and 3 cm in size. A staple suture line runs from the hilus in a cranial direction for 4 cm, and a staple suture line runs from the hilus in a caudoventral direction for 5.5 cm. At the laterobasal margin over S8-10 there is a 16 cm staple suture line demarcating an arcuate defect (status post wedge resection). Visceral pleura, accentuated lateral partly reticulate and partly patchy blackish pigmentation. Parenchyma in all segments rarefied with formation of 0.3 cm lacunae.
- 3.) Parietal pleura: 2.7 cm plate-like tissue up to 0.4 cm thick.
- 4.) Lobar LN (station 12) left upper lobe: two node parts, 0.4 cm and 1.5 cm.
- 5.) Interlobar LN (station 11) left: 1.5 cm lesioned node.
- 6.) Hilar LN (station 10) left: 1.5 cm lesioned node and a small piece of fatty tissue.
- 7.) Pulmonary ligament LN (station 9) left: two node parts, each 0.8 cm.
- 8.) Prevascular and retrotracheal LN (station 3) left: 0.8 cm node part with surrounding tissue.
- 9.) Subcarinal LN (station 7): 2.2 cm lesioned node.
- 10.) Hilar LN (station 10) right: 1.5 cm node part.
- 11.) Skin squamous epithelium left thorax: excised skin specimen measuring 2 x 0.6 cm with central button-like, raised, brown skin lesion of 0.7 cm, distance from the lateral resection margins at least 0.1 cm, at least 0.6 cm from the poles.

Examined:

- 1.) a: Rapid section remains, b+c: tumor (base marked black),
- 2.) a: 1 section below the last-named staple suture line, b: S6, c: S10, d: bronchus and vessel resection margins (tangential) and also smaller hilar node, e: larger hilar node (lamellated),
- 3.) - 10.) All material (in 3.), 6.), 9.) and 10.) lamellated in each case).
- 11.) All material (lamellated).
- 17 blocks, partly Elastica-van Gieson, PAS, diastase-PAS, iron.

Microscopy

Re 1.) Immediate intraoperative evaluation () squamous cell carcinoma.
Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Peripheral, bronchopulmonary, histologically poorly differentiated, large-cell nonkeratinizing squamous cell carcinoma of the left lower lobe of the lung evidently located in S9. TNM classification according to this picture pT1 pN3 pMX L1 R0, stage IIIB.

C 34.3;M 8070/3.

Secondary diagnosis/diagnoses:

Numerous non-necrotizing epithelioid cell granulomata, largely in paravascular interstitial sites. Slight centroacinar pulmonary emphysema (samples 1.) and 2.)). Hypocellular fibrosis area of parietal pleura (sample 3.)). Lymph nodes with large foci of epithelioid cell reaction, nodular, central partly necrotically altered areas of sclerosis and anthracotic pigment deposits (samples 4.) - 7.) and 9.)). Seborrheic keratosis of the skin of the acanthotic type (sample 11.)).

Remark/addendum:

The carcinoma shows lymphangioinvasion at the tumor margin and has produced metastases in the hilar lymph nodes of sample 2.) and in samples 8.) and 10.). The visceral pleura, the residual lower lobe of the lung, including its resection margin of bronchus and vessels, and also the lymph nodes of samples 4.) and 7.) - 9.) are tumor-free.

The distribution pattern of epithelioid cell granulomata is primarily consistent with sarcoidosis.

No asbestos bodies are found in the prepared section planes. But very much further-reaching investigations, especially dust analyses, are needed to determine the asbestos exposure of the lung.

Source: NCI Genomic Data Commons file 11801c84-a28d-49df-bf28-a83ef0dd9301 (TCGA-66-2789.50601DE1-9156-4793-9CDC-B140BB932CC0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).